Somatic mutation profile of tumor specimen 0DFJKS from CCDI case PBBSAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.7 years (6,100 days).
Specimen 0DFJKS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c332561e-bf6a-4048-8d57-642dcc2a8b05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ea13b4e-0f71-407d-9b6b-892947db2f60

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, 3'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.9805C>T p.Q3269* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | catalogued as CM122095; called by muse, mutect2
- PDGFRA | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 40/370 reads (11%) | catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- POU3F3 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TEAD4 | c.505G>C p.G169R | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, varscan2
- BAHCC1 | c.4806C>G p.P1602= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100312082, COSV57022210; called by muse, mutect2
- SDF4 | c.*46G>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1192202393; called by mutect2, varscan2
- ZMYND8 | c.2605+80A>T | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs1311453831, COSV53688450; called by muse, varscan2
